Somatic mutation profile of tumor specimen TARGET-40-PARDAX-01A (aliquot TARGET-40-PARDAX-01A-01D) from TARGET case TARGET-40-PARDAX, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 10.1 years (3,680 days).
Specimen TARGET-40-PARDAX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07d1455b-0a69-437b-bed4-5b1dca953add.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PARDAX-10A (Blood Derived Normal), aliquot TARGET-40-PARDAX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81b603ec-78d0-4e2a-888a-ff71f0cc9b9b

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 4, Silent 4, 5'Flank 1, In Frame Del 1, Frame Shift Del 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 20/29 reads (69%) | catalogued as rs121913304, CM942039, COSV57296489; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 27/35 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CFAP74 | c.915G>C p.W305C | Missense Mutation (SNP) | VAF 83/161 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV54567243; called by muse, mutect2, varscan2
- CNGA3 | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99737542; called by muse, mutect2, varscan2
- DNHD1 | c.4786C>A p.L1596I | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.631); catalogued as rs796114000; called by muse, mutect2, varscan2
- IGKV2-30 | c.215T>A p.L72Q | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768456482; called by muse, mutect2, varscan2
- LRRC8A | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs766763754; called by muse, mutect2, varscan2
- MAP3K2 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1421908432; called by muse, mutect2, varscan2
- ALG6 | c.1250A>T p.Q417L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BCL9 | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 64/288 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CARMIL1 | c.2725G>T p.D909Y | Missense Mutation (SNP) | VAF 101/288 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CCT7 | c.229_234del p.K77_T78del | In Frame Del (DEL) | VAF 66/206 reads (32%) | called by mutect2, pindel, varscan2
- ELF4 | c.1604G>C p.R535T | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- GKAP1 | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MAP3K8 | c.46T>G p.L16V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OTUD4 | c.434del p.N145Mfs*11 (on ENST00000447906 / NM_001366057.1; = p.N80Mfs*11 on NM_017493.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | called by mutect2, varscan2
- POM121L2 | c.2237C>G p.S746C | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRIM47 | c.1482C>G p.S494R | Missense Mutation (SNP) | VAF 67/129 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- VWDE | c.3159G>T p.K1053N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- CYFIP2 | c.1842C>A p.L614= (on ENST00000616178 / NM_001291722.2; = p.L589= on NM_014376.4) | Silent (SNP) | VAF 38/50 reads (76%) | called by muse, mutect2, varscan2
- ITPRID2 | c.237G>A p.A79= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1327895156; called by mutect2, varscan2
- NBAS | c.6099C>G p.P2033= | Silent (SNP) | VAF 56/142 reads (39%) | called by muse, mutect2, varscan2
- SPAM1 | c.747C>A p.L249= | Silent (SNP) | VAF 61/149 reads (41%) | called by muse, mutect2, varscan2
- ECH1 | c.*91T>C | 3'UTR (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2
- FCRLA | c.148+89A>C | Intron (SNP) | VAF 32/111 reads (29%) | called by muse, mutect2, varscan2
- HDAC3 | c.1217+79A>T | Intron (SNP) | VAF 20/106 reads (19%) | catalogued as COSV59497058; called by muse, varscan2
- NRG3 | c.824-126138T>C | Intron (SNP) | VAF 98/212 reads (46%) | called by muse, mutect2, varscan2
- RNU1-5P | chr1:16872088 C>T | 5'Flank (SNP) | VAF 6/52 reads (12%) | catalogued as rs759735964; called by mutect2, varscan2
- SLC45A4 | c.242-6464C>G | Intron (SNP) | VAF 87/317 reads (27%) | called by muse, mutect2, varscan2
